EXCEPTIONAL_RESPONDERS case ER-AC81 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b0044e63-6e2b-4939-b827-655edecbcd3f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1944; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 61.0 years (22,264 days); Year of diagnosis: 2005; AJCC staging edition: 7th; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 3,393 days (9.3 years); Days to best overall response: 865 days (2.4 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Docetaxel; Days to treatment start: 40 days; Days to treatment end: 131 days.
   Treatment given: Therapeutic agents: Trastuzumab; Days to treatment start: 40 days.
   Treatment given: Therapeutic agents: Letrozole; Days to treatment start: 250 days.

Follow-up (1 entry)
- Days to follow up: 3,393 days (9.3 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 3,393 days (9.3 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AC81-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-AC81-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 60; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
